Somatic mutation profile of tumor specimen TARGET-20-PATMNY-09A (aliquot TARGET-20-PATMNY-09A-01D) from TARGET case TARGET-20-PATMNY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.7 years (6,082 days).
Specimen TARGET-20-PATMNY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d30aa302-97f3-436c-b9f8-92ba207bf4ee.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATMNY-10A (Blood Derived Normal), aliquot TARGET-20-PATMNY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ba1ecce-5e2b-47ec-a4c5-76e773356beb

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.326A>T p.N109I (on ENST00000344691 / NM_001001890.3; = p.N136I on NM_001754.5) | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
